Gene-level copy-number profile of tumor specimen TCGA-19-0960-01A from TCGA case TCGA-19-0960, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 83.1 years (30,364 days).
Specimen TCGA-19-0960-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.eec0aa31-03d8-447a-a94a-67b4f6d33fa5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-0960-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ebd13a85-e287-4662-97b9-a0e330818bb1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,231; copy number 2: 48,863; copy number 3: 1,511; copy number 4: 928; copy number 5: 1,159; copy number 6: 77; copy number 11: 44; copy number 14: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-19-0960-01): tumor purity 0.93, ploidy 1.99, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,286 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:42,281,830–49,062,081, 77 genes, copy number 6 (broad region; genes not listed).
- chr4:53,377,839–54,295,272, 2 genes, copy number 5 (within-gene range 2–14): AC058822.1, LNX1.
- chr4:53,575,713–127,077,762, 1,024 genes, copy number 5–14 (within-gene range 1–14) (broad region; genes not listed).
- chr4:128,155,389–128,570,531, 5 genes, copy number 5: FOSL1P1, PGRMC2, LINC02615, AC110609.1, AC078850.1.
- chr12:55,572,468–59,130,875, 178 genes, copy number 5–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,231. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
